Somatic mutation profile of tumor specimen C3N-02247-72 (aliquot CPT0265300006) from CPTAC case C3N-02247, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; Tumor grade: G2.
Specimen C3N-02247-72: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e994b935-f11f-49f2-a796-29531993870c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02247-31 (Blood Derived Normal), aliquot CPT0264040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec73623e-5c31-4666-8f09-3d30e10b36ba

The open-access MAF lists 962 somatic variants for this specimen: 646 protein-altering or splice-affecting, 208 silent, 108 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 467, Silent 208, Frame Shift Del 107, Intron 60, Frame Shift Ins 25, Nonsense Mutation 22, 3'UTR 17, 5'UTR 14, Splice Region 13, Splice Site 7, RNA 7, In Frame Del 5.

Variants (750 of 962; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTK | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 54/416 reads (13%) | catalogued as rs128620187, CM940182, COSV58118363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EIF1AX | c.17-2A>G p.X6_splice | Splice Site (SNP) | VAF 18/139 reads (13%) | hotspot (GDC flag); catalogued as COSV63309299, COSV63309333; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 62/350 reads (18%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- RYR2 | c.7159G>A p.A2387T | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs794728753, CM056386, HM030024, COSV100770091; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC138647.1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.009); catalogued as rs1175797325; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 34/186 reads (18%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS13 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 85/648 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs782454600; called by muse, mutect2, varscan2
- ADRA1D | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1233125971; called by muse, mutect2, varscan2
- ADRA2A | c.107del p.G36Afs*12 | Frame Shift Del (DEL) | VAF 19/142 reads (13%) | catalogued as rs1554870245; called by mutect2, pindel, varscan2
- AGRN | c.3074G>A p.R1025Q | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs372696395; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH3A1 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs554254701; called by muse, mutect2, varscan2
- ALPK3 | c.3647C>T p.T1216M | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs767667447; called by muse, mutect2
- AMMECR1 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs763040190, COSV53320051; called by muse, mutect2
- ANK1 | c.3842G>A p.R1281Q | Missense Mutation (SNP) | VAF 44/367 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1481858393; called by muse, mutect2, varscan2
- ANK1 | c.3526G>A p.V1176I | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs1321444548, COSV55877451; called by muse, mutect2, varscan2
- ANKH | c.1067T>C p.I356T | Missense Mutation (SNP) | VAF 78/559 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV99415687; called by muse, mutect2, varscan2
- ANO7 | c.1030G>A p.A344T (on ENST00000274979; = p.A290T on NM_001370694.2) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs369129557; called by muse, mutect2, varscan2
- ANO9 | c.2023G>A p.V675M | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs367921445; called by muse, mutect2
- ANPEP | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 13/293 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1456553395, COSV55589443; called by muse, mutect2
- APCDD1 | c.1106T>C p.M369T | Missense Mutation (SNP) | VAF 46/472 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.62); catalogued as rs751310085; called by muse, mutect2, varscan2
- APEX2 | c.1076A>C p.H359P | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100237887; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 47/273 reads (17%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGEF37 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs372584659; called by muse, mutect2, varscan2
- ARHGEF6 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 78/462 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51691520; called by muse, mutect2, varscan2
- ARID1B | c.5495G>A p.R1832H | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs374035954; called by muse, mutect2, varscan2
- ARID3B | c.879G>A p.T293= | Splice Region (SNP) | VAF 13/78 reads (17%) | catalogued as rs1230890061; called by muse, mutect2, varscan2
- ASCL4 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 60/429 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as rs761289333, COSV60817002; called by muse, mutect2, varscan2
- ASTN2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs1178861666, COSV57793827, COSV57798910; called by muse, mutect2
- ASXL3 | c.4409C>T p.P1470L | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1297982117, COSV52456427, COSV52473229; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 38/280 reads (14%) | catalogued as rs35951843; called by mutect2, varscan2
- BAIAP3 | c.3272C>T p.A1091V | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs144679706; called by muse, mutect2, varscan2
- BEAN1 | c.230A>G p.H77R | Missense Mutation (SNP) | VAF 52/320 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100227987; called by mutect2, varscan2
- BIRC6 | c.5318C>T p.P1773L | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1283501394; called by muse, varscan2
- BMPR1A | c.509_511del p.F170del | In Frame Del (DEL) | VAF 57/440 reads (13%) | catalogued as rs878854669; called by pindel, varscan2
- BRAT1 | c.636dup p.K213Qfs*190 | Frame Shift Ins (INS) | VAF 18/138 reads (13%) | catalogued as COSV61394809; called by mutect2, pindel
- BRPF1 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769439953, COSV57403677; called by muse, mutect2, varscan2
- BTG3 | c.736C>A p.P246T | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.908); catalogued as COSV60287172; called by muse, mutect2
- C10orf90 | c.395del p.G132Afs*76 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | catalogued as rs756932045; called by mutect2, varscan2
- C2CD2 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 60/439 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100298132, COSV61600089, COSV61600804; called by muse, mutect2, varscan2
- C8orf89 | c.457del p.S153Afs*16 | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | catalogued as rs951061763; called by mutect2, varscan2
- CACNA1A | c.3376C>T p.R1126C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as rs774407963, COSV100800976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.6122G>A p.R2041H | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs201543308; called by muse, mutect2, varscan2
- CADM3 | c.352C>T p.R118* (on ENST00000368125 / NM_001127173.3; = p.R152* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 24/258 reads (9%) | catalogued as rs983781182, COSV63685158; called by muse, mutect2
- CAMTA1 | c.4667G>A p.R1556H | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1233149008; called by muse, mutect2, varscan2
- CARS2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as rs140084443; called by muse, mutect2, varscan2
- CCDC59 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs201791556; called by muse, mutect2, varscan2
- CCDC92 | c.544G>T p.G182W | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV53022580; called by muse, mutect2, varscan2
- CDC73 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 28/586 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs1244272523; called by muse, mutect2
- CEL | c.460G>A p.A154T (on ENST00000673714; = p.A151T on NM_001807.6) | Missense Mutation (SNP) | VAF 90/653 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs373668445, COSV60826960; called by muse, mutect2, varscan2
- CELSR1 | c.3862C>T p.R1288W | Missense Mutation (SNP) | VAF 52/387 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769121510; called by muse, mutect2, varscan2
- CEMIP2 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1489451937; called by muse, mutect2, varscan2
- CFAP410 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 20/321 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs779474015; called by muse, mutect2
- CHD8 | c.5654G>T p.R1885L (on ENST00000646647 / NM_001170629.2; = p.R1606L on NM_020920.4) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV100765284, COSV100765390; called by muse, mutect2, varscan2
- CHRNB3 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51494964; called by muse, mutect2, varscan2
- CHTF18 | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 58/457 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV50099812, COSV99135755; called by muse, mutect2, varscan2
- CLASP2 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV56275283; called by muse, mutect2
- CLCN4 | c.1777C>A p.R593S | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV66465228; called by muse, mutect2, varscan2
- CLEC14A | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.094); catalogued as rs748630764; called by muse, mutect2, varscan2
- CNTN3 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751612030; called by muse, mutect2, varscan2
- CNTN4 | c.2017C>T p.R673C | Missense Mutation (SNP) | VAF 100/633 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs530287934, COSV61872950; called by muse, mutect2, varscan2
- COL6A3 | c.6312C>T p.G2104= | Splice Region (SNP) | VAF 89/554 reads (16%) | catalogued as rs377074792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.5684C>T p.S1895L | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs760532694, COSV99800933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPED1 | c.2778del p.K926Nfs*6 | Frame Shift Del (DEL) | VAF 29/199 reads (15%) | catalogued as rs777945397; called by mutect2, pindel, varscan2
- CUEDC1 | c.332del p.P111Rfs*136 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | catalogued as COSV100804649, COSV64227288; called by mutect2, pindel, varscan2
- CUX1 | c.300A>C p.Q100H (on ENST00000292535 / NM_181552.4; = p.Q111H on NM_001913.5) | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1554484593; called by muse, mutect2, varscan2
- CXXC1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs1342993263, COSV53275931; called by muse, mutect2, varscan2
- CYCS | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 51/399 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as rs573366932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP27B1 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 111/689 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as COSV56985694; called by muse, mutect2, varscan2
- CYP4V2 | c.1062dup p.V355Sfs*4 | Frame Shift Ins (INS) | VAF 82/618 reads (13%) | catalogued as rs1280925919; called by mutect2, pindel, varscan2
- DAB2IP | c.1213G>A p.G405R (on ENST00000408936; = p.G377R on NM_032552.3) | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.57); PolyPhen probably damaging (1); catalogued as rs142519289; called by muse, mutect2, varscan2
- DACT1 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 54/333 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs778143201; called by muse, mutect2, varscan2
- DCTN1 | c.3197-8G>A | Splice Region (SNP) | VAF 70/479 reads (15%) | catalogued as rs371393698; called by muse, mutect2, varscan2
- DNAAF5 | c.1625C>T p.T542M | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs751822366; called by muse, mutect2, varscan2
- DNAH17 | c.6461C>T p.A2154V | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs930692277; called by muse, mutect2, varscan2
- DNAH2 | c.10202C>T p.A3401V | Missense Mutation (SNP) | VAF 34/391 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749752088; called by muse, mutect2
- DNAH5 | c.13798G>A p.A4600T | Missense Mutation (SNP) | VAF 56/411 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs774279588, COSV54241462; called by muse, mutect2, varscan2
- DNMBP | c.4372C>T p.Q1458* | Nonsense Mutation (SNP) | VAF 65/380 reads (17%) | catalogued as COSV60626045; called by muse, mutect2, varscan2
- DPEP2 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.18); catalogued as COSV52053835; called by muse, mutect2, varscan2
- DPH7 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 38/322 reads (12%) | catalogued as rs1564428205, COSV53023896, COSV99483395; called by muse, mutect2, varscan2
- DPP9 | c.1148del p.P383Rfs*15 (on ENST00000598800; = p.P412Rfs*15 on NM_139159.5) | Frame Shift Del (DEL) | VAF 16/110 reads (15%) | catalogued as rs747759328, COSV53593143; called by mutect2, pindel
- DUS1L | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs201410540; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 20/122 reads (16%) | catalogued as rs755197346; called by mutect2, varscan2
- EFCAB5 | c.450del p.K150Nfs*17 | Frame Shift Del (DEL) | VAF 20/134 reads (15%) | catalogued as rs760813779; called by mutect2, varscan2
- EFNB3 | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.34); catalogued as rs1397849067; called by muse, mutect2, varscan2
- EGR1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53521712; called by muse, mutect2, varscan2
- EIF2AK1 | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV52241155; called by muse, mutect2, varscan2
- EIF5A | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 133/782 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV59749160; called by muse, mutect2, varscan2
- EML6 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 58/407 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1271262535, COSV62872242; called by muse, mutect2, varscan2
- ENOSF1 | c.738del p.Y247Tfs*6 (on ENST00000340116 / NM_001354066.2; = p.Y199Tfs*6 on NM_017512.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 39/364 reads (11%) | catalogued as rs1443993063; called by mutect2, pindel, varscan2
- ERLEC1 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 53/483 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs199616024; called by muse, mutect2, varscan2
- FAM160A2 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755128997; called by muse, mutect2, varscan2
- FAM180A | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV58527825; called by muse, mutect2, varscan2
- FAM234A | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT tolerated (0.91); PolyPhen benign (0.023); catalogued as rs985459676; called by muse, mutect2
- FAM98C | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs764264994; called by mutect2, varscan2
- FBXO31 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 54/367 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs376226613, COSV61149780; called by muse, mutect2, varscan2
- FBXO38 | c.3382G>A p.E1128K (on ENST00000340253 / NM_205836.3; = p.E1053K on NM_030793.5) | Missense Mutation (SNP) | VAF 43/318 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57027167; called by muse, mutect2, varscan2
- FGF5 | c.441del p.G148Efs*45 | Frame Shift Del (DEL) | VAF 20/173 reads (12%) | catalogued as rs35667286; called by mutect2, pindel, varscan2
- FHOD1 | c.2720G>A p.R907Q | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs752798062; called by muse, mutect2
- FLNA | c.4723G>A p.A1575T | Missense Mutation (SNP) | VAF 101/585 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1557177233; called by muse, mutect2, varscan2
- FLNC | c.2363C>T p.T788M | Missense Mutation (SNP) | VAF 56/386 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010774264; called by muse, mutect2, varscan2
- FTCD | c.517del p.A173Pfs*44 | Frame Shift Del (DEL) | VAF 39/264 reads (15%) | catalogued as rs753817415; called by mutect2, pindel, varscan2
- FYN | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 32/239 reads (13%) | catalogued as COSV57609584; called by muse, mutect2, varscan2
- GALNT14 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); catalogued as rs150049844; called by muse, mutect2, varscan2
- GIMAP2 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs146899946; called by muse, mutect2, varscan2
- GLI2 | c.2776G>A p.G926R (on ENST00000361492 / NM_001374353.1; = p.G943R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs1312020540; called by muse, mutect2, varscan2
- GNAI1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs778777547; called by muse, mutect2, varscan2
- GNAZ | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 68/522 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs775149885, COSV50737670; called by muse, mutect2, varscan2
- GPER1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.636); catalogued as rs867029251; called by muse, mutect2, varscan2
- GPRIN1 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199526684; called by muse, mutect2, varscan2
- H3-4 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 61/568 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs757564822, COSV64210620, COSV64210829; called by muse, mutect2, varscan2
- HCRTR2 | c.32dup p.C12Lfs*12 | Frame Shift Ins (INS) | VAF 100/587 reads (17%) | catalogued as rs755844571; called by mutect2, varscan2
- HDLBP | c.1993C>T p.H665Y | Missense Mutation (SNP) | VAF 46/498 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); catalogued as COSV60502030; called by muse, mutect2
- HEATR1 | c.6151C>T p.Q2051* | Nonsense Mutation (SNP) | VAF 30/316 reads (9%) | catalogued as COSV59380577; called by muse, mutect2
- HEATR5B | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs369680339, COSV51850221; called by muse, mutect2, varscan2
- HIC2 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68041790, COSV68042922; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPU | c.1507G>A p.V503M (on ENST00000283179; = p.V565M on NM_004501.3) | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV104392558; called by muse, mutect2, varscan2
- HRNR | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 51/433 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs144722087; called by muse, mutect2, varscan2
- HSD17B7 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs560193106, COSV54417783; called by muse, mutect2
- IGFBP4 | c.123del p.V42Wfs*52 | Frame Shift Del (DEL) | VAF 42/312 reads (13%) | catalogued as rs778799414; called by mutect2, pindel, varscan2
- IGFBPL1 | c.562T>C p.W188R | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757817834; called by muse, varscan2
- IGSF21 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as rs776112850, COSV52145354; called by muse, mutect2, varscan2
- INPPL1 | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 41/322 reads (13%) | catalogued as rs781674896, CM130298; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 19/137 reads (14%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ISM2 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs553107946; called by muse, mutect2, varscan2
- ITGA7 | c.3103G>A p.V1035M (on ENST00000555728; = p.V991M on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/652 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.186); catalogued as rs1268555212; called by muse, mutect2
- ITPR3 | c.2627A>G p.Y876C | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs982823690; called by muse, mutect2, varscan2
- ITPRIP | c.383del p.G128Afs*48 | Frame Shift Del (DEL) | VAF 25/189 reads (13%) | catalogued as rs751596276; called by mutect2, pindel, varscan2
- JAG2 | c.1429-5C>T | Splice Region (SNP) | VAF 22/741 reads (3%) | catalogued as rs1369439581; called by muse, mutect2
- JUP | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs782341732, COSV60278206; ClinVar: uncertain significance; called by muse, mutect2
- KAT2A | c.208del p.A70Pfs*12 | Frame Shift Del (DEL) | VAF 27/190 reads (14%) | catalogued as rs782561411; called by mutect2, pindel, varscan2
- KCNC2 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 15/384 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs974407730; called by muse, mutect2
- KCNC3 | c.1880del p.G627Efs*27 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | catalogued as rs1159900432; called by mutect2, pindel, varscan2
- KCNN3 | c.1820T>C p.I607T (on ENST00000618040 / NM_001204087.1; = p.I592T on NM_002249.6) | Missense Mutation (SNP) | VAF 78/710 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs952407124; called by muse, mutect2, varscan2
- KCNT1 | c.3299G>A p.R1100Q (on ENST00000488444; = p.R1126Q on NM_020822.3) | Missense Mutation (SNP) | VAF 92/523 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs769135500, COSV53709010; called by muse, mutect2, varscan2
- KDM6A | c.3331C>T p.R1111C | Missense Mutation (SNP) | VAF 84/458 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs763592177, COSV65038074, COSV65038305, COSV65040911, COSV65042699; called by muse, mutect2, varscan2
- KHSRP | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as rs1390238201; called by muse, mutect2, varscan2
- KIAA1217 | c.3050del p.G1017Efs*117 | Frame Shift Del (DEL) | VAF 36/208 reads (17%) | catalogued as COSV56823647; called by mutect2, pindel, varscan2
- KIAA1614 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535764234; called by muse, mutect2, varscan2
- KIF1B | c.2708G>A p.R903H (on ENST00000377086 / NM_001365952.1; = p.R857H on NM_015074.3) | Missense Mutation (SNP) | VAF 60/472 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs778403355; called by muse, mutect2, varscan2
- KIF27 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs773750084; called by muse, mutect2, varscan2
- KIRREL1 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.306); catalogued as rs748532476, COSV63285751; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 14/108 reads (13%) | catalogued as COSV54711577; called by pindel, varscan2
- LAMA5 | c.2775del p.D926Tfs*15 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | catalogued as rs112350373; called by mutect2, pindel, varscan2
- LAMA5 | c.1568G>A p.G523D | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747927662; called by muse, mutect2, varscan2
- LFNG | c.844G>A p.A282T (on ENST00000222725 / NM_001040167.2; = p.A153T on NM_002304.2) | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV56069311; called by muse, mutect2, varscan2
- LLGL2 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs760735734, COSV99390748; called by muse, mutect2, varscan2
- LMF2 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 58/378 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs778224974; called by muse, mutect2, varscan2
- LRATD2 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 67/526 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs373050263; called by muse, mutect2, varscan2
- MAML3 | c.3263C>T p.A1088V | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as COSV72208883; called by muse, mutect2, varscan2
- MAPK14 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758211646, COSV57695720; called by muse, mutect2, varscan2
- MBD6 | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 58/347 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV63075669; called by muse, mutect2, varscan2
- MCPH1 | c.1987G>A p.V663I | Missense Mutation (SNP) | VAF 56/381 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs752602108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MED12 | c.4210G>A p.A1404T | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV61341340; called by muse, mutect2
- MGAT2 | c.655T>C p.F219L | Missense Mutation (SNP) | VAF 99/649 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs747616287; called by muse, mutect2, varscan2
- MIDEAS | c.2386C>T p.H796Y | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as rs1483919177; called by muse, mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 35/176 reads (20%) | catalogued as rs749903408; called by mutect2, varscan2
- MN1 | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs775728511, COSV56562513; called by muse, mutect2, varscan2
- MOGS | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745841543, COSV99270225; called by muse, mutect2, varscan2
- MSANTD1 | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as COSV70873258; called by muse, mutect2, varscan2
- MSC | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 61/380 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183172324, COSV100335893; called by muse, mutect2, varscan2
- MTRNR2L6 | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 24/178 reads (13%) | PolyPhen benign (0); catalogued as rs1315935958; called by muse, mutect2, varscan2
- MUC4 | c.5575G>A p.V1859I | Missense Mutation (SNP) | VAF 23/652 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.101); catalogued as rs760319053; called by muse, mutect2
- MUC5AC | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); catalogued as rs773114226, COSV62253478; called by muse, mutect2, varscan2
- MUC5AC | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 82/462 reads (18%) | SIFT deleterious (0); catalogued as rs770614106, COSV100650750; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 34/251 reads (14%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYF5 | c.350G>T p.R117M | Missense Mutation (SNP) | VAF 102/603 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57355749; called by muse, mutect2, varscan2
- MYH7B | c.5114G>A p.R1705Q | Missense Mutation (SNP) | VAF 21/267 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs558448583; called by muse, mutect2
- MYO18A | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs760272640; called by muse, mutect2, varscan2
- MYO9B | c.6049dup p.A2017Gfs*183 | Frame Shift Ins (INS) | VAF 35/330 reads (11%) | catalogued as rs1325294870, COSV55728921; called by mutect2, pindel, varscan2
- NCOR2 | c.5417G>T p.R1806L | Missense Mutation (SNP) | VAF 59/415 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100657313; called by muse, mutect2, varscan2
- NEIL2 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 63/412 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs762855900; called by muse, mutect2, varscan2
- NETO1 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs760230093, COSV55007207; called by muse, mutect2, varscan2
- NFIB | c.626A>G p.E209G | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs867224441; called by muse, mutect2
- NFIX | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.282); catalogued as rs1474950210; called by muse, mutect2, varscan2
- NFS1 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV60764830; called by muse, mutect2, varscan2
- NKTR | c.3503C>T p.T1168M | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs571337393, COSV99236449; called by muse, mutect2, varscan2
- NLRP1 | c.2959C>T p.R987W | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199748129, COSV52563658, COSV52572656; called by muse, mutect2, varscan2
- NOD2 | c.1515dup p.S506Vfs*73 | Frame Shift Ins (INS) | VAF 32/219 reads (15%) | catalogued as rs754761524; ClinVar: uncertain significance; called by mutect2, varscan2
- NOP14 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs376246926; called by muse, mutect2, varscan2
- NUDT16 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1214148554, COSV100720814, COSV63248311; called by muse, mutect2, varscan2
- NUP214 | c.2824A>G p.M942V | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774871742; called by muse, mutect2
- NYX | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 123/807 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs372496317, COSV61180676; called by muse, mutect2, varscan2
- OBSCN | c.9259G>A p.A3087T | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1163159360, COSV52771070; called by muse, mutect2
- OPN1SW | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201892828, COSV99975667; called by muse, mutect2
- OR10H2 | c.533del p.L178Yfs*8 | Frame Shift Del (DEL) | VAF 18/133 reads (14%) | catalogued as COSV59946147; called by mutect2, pindel, varscan2
- OR10P1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 38/241 reads (16%) | catalogued as rs1252391226; called by muse, mutect2, varscan2
- OR10T2 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749446051; called by muse, mutect2
- OR10Z1 | c.775T>C p.Y259H | Missense Mutation (SNP) | VAF 60/456 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1332311828; called by muse, mutect2, varscan2
- OR2L5 | c.530dup p.C178Lfs*2 | Frame Shift Ins (INS) | VAF 42/427 reads (10%) | catalogued as rs749963203; called by mutect2, pindel
- OR2T1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as rs769496239; called by muse, mutect2
- OR51I2 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as rs776168838; called by muse, mutect2, varscan2
- OR5AP2 | c.192del p.M65Cfs*11 | Frame Shift Del (DEL) | VAF 33/234 reads (14%) | catalogued as COSV57256925; called by mutect2, pindel, varscan2
- OR6P1 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 46/553 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs1336760003; called by muse, mutect2
- PAPOLG | c.1803dup p.T602Hfs*16 | Frame Shift Ins (INS) | VAF 25/208 reads (12%) | catalogued as rs1251178026; called by mutect2, pindel, varscan2
- PCDH17 | c.1514G>A p.G505D | Missense Mutation (SNP) | VAF 70/407 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64976940; called by muse, mutect2, varscan2
- PCDHA8 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 74/512 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV65325085; called by muse, mutect2, varscan2
- PCDHAC2 | c.1706T>C p.V569A | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs1554230782; called by muse, mutect2, varscan2
- PCDHAC2 | c.2408G>A p.S803N | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs777458792; called by muse, mutect2, varscan2
- PCDHB7 | c.2221G>T p.G741W | Missense Mutation (SNP) | VAF 58/420 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1365099109; called by muse, mutect2, varscan2
- PCM1 | c.6003G>A p.M2001I | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as rs1273969576, COSV59585620; called by muse, mutect2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | catalogued as rs759495724; called by mutect2, varscan2
- PGBD2 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 62/564 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1169775415, COSV100252297, COSV61400378; called by muse, mutect2, varscan2
- PHF1 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.116); catalogued as rs368864667; called by muse, mutect2, varscan2
- PIAS2 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs533422652, COSV61342735; called by muse, mutect2, varscan2
- PIK3C2G | c.4138G>A p.E1380K (on ENST00000676171; = p.E1339K on NM_004570.5) | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs770728627; called by muse, mutect2, varscan2
- PIK3R4 | c.2809A>T p.I937F | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100768406; called by muse, mutect2, varscan2
- PIK3R4 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 50/337 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63239825; called by muse, mutect2, varscan2
- PITPNM2 | c.3778C>T p.R1260W | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as rs751854596, COSV54908970; called by muse, mutect2
- PLEKHG4 | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 73/444 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs995725297; called by muse, mutect2, varscan2
- PLIN5 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs762421444; called by muse, mutect2, varscan2
- PLIN5 | c.793del p.E265Nfs*26 | Frame Shift Del (DEL) | VAF 30/165 reads (18%) | catalogued as rs764473017; called by mutect2, pindel, varscan2
- PLPPR5 | c.195dup p.V66Rfs*33 | Frame Shift Ins (INS) | VAF 37/222 reads (17%) | catalogued as rs1481324917; called by mutect2, pindel, varscan2
- POLR3D | c.823C>A p.L275I | Missense Mutation (SNP) | VAF 96/547 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.642); catalogued as COSV100120164; called by muse, mutect2, varscan2
- POLR3GL | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 22/440 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV65215455; called by muse, mutect2
- PON1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as rs1359250281; called by muse, mutect2, varscan2
- PPFIBP2 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 56/323 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as rs201101900; called by muse, mutect2, varscan2
- PPP1R3F | c.1404del p.L469Wfs*4 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as COSV104379330; called by mutect2, pindel, varscan2
- PPRC1 | c.2819del p.P940Hfs*6 | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | catalogued as rs768056539; called by mutect2, varscan2
- PROSER2 | c.916del p.A306Pfs*47 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs1474543121; called by mutect2, pindel
- PRR23C | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.316); catalogued as rs543451209; called by muse, mutect2, varscan2
- PRRC2A | c.3665C>T p.A1222V | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs111606459; called by muse, mutect2, varscan2
- PTEN | c.741del p.L247Ffs*9 | Frame Shift Del (DEL) | VAF 119/440 reads (27%) | catalogued as COSV64308201; called by mutect2, pindel, varscan2
- PTPN23 | c.3979G>A p.E1327K | Missense Mutation (SNP) | VAF 49/323 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as rs759389182, COSV55546032; called by muse, mutect2, varscan2
- PYGB | c.1874C>T p.T625I | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs199553206; called by muse, mutect2, varscan2
- QSER1 | c.3661A>T p.K1221* (on ENST00000399302; = p.K1350* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 22/140 reads (16%) | catalogued as rs779414810; called by muse, mutect2, varscan2
- RAP2C | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs749217667, COSV100747312; called by muse, mutect2, varscan2
- RBM47 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 55/476 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs1370745590, COSV55931603; called by muse, mutect2, varscan2
- RBMXL2 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); catalogued as rs1261935346; called by muse, mutect2, varscan2
- RBPJL | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV59213219; called by muse, mutect2, varscan2
- REM1 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs1221209410; called by muse, mutect2, varscan2
- REPIN1 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs755658442; called by muse, mutect2, varscan2
- RET | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 72/451 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.018); catalogued as COSV60702479; called by muse, mutect2, varscan2
- RGMB | c.814C>T p.H272Y (on ENST00000513185 / NM_001366508.1; = p.H313Y on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as rs1419574738; called by muse, mutect2
- RNF169 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770798939; called by muse, mutect2, varscan2
- RNF214 | c.678G>A p.L226= | Splice Region (SNP) | VAF 20/174 reads (11%) | catalogued as COSV56120025; called by muse, mutect2, varscan2
- RP1L1 | c.2380del p.E794Kfs*135 | Frame Shift Del (DEL) | VAF 32/233 reads (14%) | catalogued as rs777947978; called by mutect2, pindel, varscan2
- RPS4X | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100289152; called by muse, mutect2, varscan2
- RPS6KA1 | c.1104dup p.S369Qfs*47 | Frame Shift Ins (INS) | VAF 24/133 reads (18%) | catalogued as rs745561139; called by mutect2, varscan2
- RTL6 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.947); catalogued as rs754402274; called by muse, mutect2, varscan2
- RUNX1 | c.1319C>T p.A440V (on ENST00000344691 / NM_001001890.3; = p.A467V on NM_001754.5) | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.818); catalogued as rs1442794209, COSV55869420; called by muse, mutect2
- RYR2 | c.4735G>A p.V1579M | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as rs763389778, COSV63658397, COSV63695377; called by muse, mutect2, varscan2
- SASH1 | c.3177del p.W1060Gfs*16 | Frame Shift Del (DEL) | VAF 32/242 reads (13%) | catalogued as rs761606832; called by mutect2, pindel, varscan2
- SASH1 | c.3445C>T p.R1149W | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408143617; called by muse, mutect2
- SEC14L5 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1479689819, COSV52038785; called by muse, mutect2
- SEMA4F | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 12/130 reads (9%) | catalogued as rs757587166; called by muse, mutect2
- SEZ6L | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs1247551394, COSV50669338, COSV50680441; called by muse, mutect2, varscan2
- SFTPB | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs925336255; called by muse, mutect2, varscan2
- SH3BP5L | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.63); catalogued as rs141743810, COSV100821933; called by muse, mutect2, varscan2
- SHH | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV51919163; called by muse, mutect2, varscan2
- SHROOM4 | c.55dup p.A19Gfs*8 | Frame Shift Ins (INS) | VAF 31/270 reads (11%) | catalogued as rs782677387; called by mutect2, varscan2
- SIGLEC10 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs775153809; called by muse, mutect2, varscan2
- SINHCAF | c.218del p.N73Tfs*6 | Frame Shift Del (DEL) | VAF 18/114 reads (16%) | catalogued as rs771414532; called by mutect2, varscan2
- SIRT2 | c.748-4G>A | Splice Region (SNP) | VAF 41/224 reads (18%) | catalogued as rs779821357; called by muse, mutect2, varscan2
- SLC12A9 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769808948; called by muse, mutect2, varscan2
- SLC17A8 | c.410dup p.W138Lfs*20 | Frame Shift Ins (INS) | VAF 57/436 reads (13%) | catalogued as rs777395094; called by mutect2, pindel, varscan2
- SLC24A4 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs745385207, COSV100106203; called by muse, mutect2, varscan2
- SLC25A16 | c.357G>A p.T119= | Splice Region (SNP) | VAF 13/74 reads (18%) | catalogued as rs1433912916, COSV56264166; called by muse, mutect2
- SLC26A1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs387907486; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SLC39A7 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs761507386; called by muse, mutect2, varscan2
- SLC41A2 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs769657162; called by muse, mutect2, varscan2
- SLC45A1 | c.2015G>A p.G672D | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99239298; called by muse, mutect2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 17/143 reads (12%) | catalogued as rs753589038, COSV53507811; called by mutect2, pindel, varscan2
- SMARCD3 | c.473G>A p.R158Q (on ENST00000262188 / NM_001003801.2; = p.R145Q on NM_003078.4) | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756509887; called by muse, mutect2, varscan2
- SMURF2 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782135506; called by muse, mutect2
- SOX11 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 84/453 reads (19%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as rs772309412; called by muse, mutect2, varscan2
- SOX9 | c.788del p.G263Afs*16 | Frame Shift Del (DEL) | VAF 70/431 reads (16%) | catalogued as rs1274036689; called by mutect2, pindel, varscan2
- SPATA20 | c.2113G>A p.V705M (on ENST00000356488 / NM_001258372.1; = p.V721M on NM_022827.4) | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1028500817; called by muse, mutect2, varscan2
- SPATA21 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs954572280; called by muse, mutect2, varscan2
- SPATA31D1 | c.1268del p.G423Vfs*4 | Frame Shift Del (DEL) | VAF 68/568 reads (12%) | catalogued as rs1564173843; called by mutect2, varscan2
- SPESP1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 59/428 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.373); catalogued as rs368487764; called by muse, mutect2, varscan2
- SPTBN5 | c.7769G>A p.R2590H | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs773933741; called by muse, mutect2, varscan2
- SRCAP | c.4708G>A p.A1570T | Missense Mutation (SNP) | VAF 52/337 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs757389822; called by muse, mutect2, varscan2
- SRRM2 | c.6233G>A p.R2078H | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs771816164, COSV51941533; called by muse, mutect2, varscan2
- SSC5D | c.2482G>A p.G828S | Missense Mutation (SNP) | VAF 69/494 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229591186, COSV101046593; called by muse, mutect2, varscan2
- ST13 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as rs749274921, COSV53424044; called by muse, mutect2
- SUPT6H | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs1169154332; called by muse, mutect2, varscan2
- SVIL | c.5656G>A p.V1886M (on ENST00000355867 / NM_021738.3; = p.V1460M on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/289 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs1406921284, COSV63445772; called by muse, mutect2, varscan2
- SYMPK | c.3065G>A p.R1022H | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201053291; called by muse, mutect2
- SYNE1 | c.11414G>A p.R3805Q (on ENST00000367255 / NM_182961.4; = p.R3790Q on NM_033071.3) | Missense Mutation (SNP) | VAF 57/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754270893, COSV54921171, COSV55010734; called by muse, mutect2, varscan2
- SYNE2 | c.5752G>A p.V1918M | Missense Mutation (SNP) | VAF 80/430 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs199898588; called by muse, mutect2, varscan2
- TAOK1 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs765001845; called by muse, mutect2, varscan2
- TAS1R3 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 93/630 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs1158201090; called by muse, mutect2, varscan2
- TBC1D13 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs562060342; called by muse, mutect2, varscan2
- TBC1D22B | c.530del p.P177Qfs*2 | Frame Shift Del (DEL) | VAF 19/137 reads (14%) | catalogued as rs757209781; called by mutect2, pindel, varscan2
- TBX20 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs201217462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF25 | c.409A>G p.S137G | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1355080683; called by muse, mutect2, varscan2
- TCL1B | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs540251214; called by muse, mutect2, varscan2
- TDRD5 | c.2220G>A p.W740* | Nonsense Mutation (SNP) | VAF 18/153 reads (12%) | catalogued as COSV54242477; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 38/192 reads (20%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM2 | c.3488C>T p.T1163I (on ENST00000518659 / NM_001122679.2; = p.T931I on NM_001080428.3) | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1326968491; called by muse, mutect2, varscan2
- TENM2 | c.6724C>T p.R2242C (on ENST00000518659 / NM_001122679.2; = p.R2003C on NM_001080428.3) | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777269622, COSV101317975, COSV69122800; called by muse, mutect2, varscan2
- THEMIS | c.1218del p.V407Wfs*2 | Frame Shift Del (DEL) | VAF 18/109 reads (17%) | catalogued as rs1425728909; called by mutect2, pindel, varscan2
- THSD4 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1343017578; called by muse, mutect2, varscan2
- TMC7 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs1287293938; called by muse, mutect2, varscan2
- TMEM127 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 87/477 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.127); catalogued as rs746831347, COSV51497970; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TMPRSS6 | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 53/395 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs201126963, COSV60974280; called by muse, mutect2, varscan2
- TNS4 | c.176G>A p.C59Y | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs774885549, COSV54187889, COSV99564196; called by muse, mutect2, varscan2
- TPMT | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 83/548 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); catalogued as COSV59429778; called by muse, mutect2, varscan2
- TPR | c.4001G>A p.R1334H | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs758704152, COSV100824122; called by muse, mutect2
- TRA2B | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV99373245; called by muse, mutect2, varscan2
- TRANK1 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.789); catalogued as COSV57157505; called by muse, mutect2, varscan2
- TRPC3 | c.259C>T p.R87W (on ENST00000379645 / NM_001366479.2; = p.R14W on NM_003305.2) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as rs778212103; called by muse, mutect2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTN | c.90244_90246del p.E30082del (on ENST00000591111; = p.E22658del on NM_003319.4) | In Frame Del (DEL) | VAF 12/87 reads (14%) | catalogued as rs771084968; called by mutect2, pindel
- UGT1A5 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 44/349 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs369417360, COSV59397276; called by muse, mutect2, varscan2
- VEGFA | c.544del p.H182Ifs*39 (on ENST00000523873 / NM_001171623.1; = p.H362Ifs*39 on NM_001025366.3) | Frame Shift Del (DEL) | VAF 65/453 reads (14%) | catalogued as rs374210528; called by mutect2, pindel, varscan2
- WDR76 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 20/209 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs768457904, COSV55478039; called by muse, mutect2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 36/178 reads (20%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WIPF3 | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as rs375082324; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 35/292 reads (12%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- ZBTB20 | c.1230G>C p.E410D (on ENST00000474710 / NM_001164342.2; = p.E337D on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV61852184; called by muse, mutect2, varscan2
- ZBTB7A | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 46/339 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV59326761; called by muse, mutect2, varscan2
- ZC2HC1A | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as rs1276766704; called by muse, mutect2
- ZDHHC8 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs748776670; called by muse, mutect2, varscan2
- ZFHX3 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780015879; called by muse, mutect2, varscan2
- ZMYM3 | c.1235G>A p.C412Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58739165; called by muse, mutect2, varscan2
- ZNF205 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.381); catalogued as rs1467022048; called by muse, mutect2, varscan2
- ZNF208 | c.3826A>G p.T1276A | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV101237255; called by muse, mutect2, varscan2
- ZNF469 | c.3776C>T p.T1259M (on ENST00000437464; = p.T1287M on NM_001367624.2) | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs953976462; called by muse, mutect2
- ZNF479 | c.381del p.K127Nfs*74 | Frame Shift Del (DEL) | VAF 44/340 reads (13%) | catalogued as rs782331095; called by mutect2, varscan2
- ZNF512B | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1252054838, COSV53865351; called by muse, mutect2, varscan2
- ZNF648 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 85/753 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1444857527; called by muse, mutect2, varscan2
- ZNF70 | c.242del p.P81Qfs*26 | Frame Shift Del (DEL) | VAF 34/319 reads (11%) | catalogued as rs775749922; called by mutect2, pindel, varscan2
- ZNF784 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100323211, COSV100323261; called by muse, mutect2, varscan2
- ZNF792 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs138080556, COSV101289766; called by muse, mutect2, varscan2
- ZNF813 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV101125032; called by muse, mutect2, varscan2
- ZNF83 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.515); catalogued as rs369717102; called by muse, mutect2, varscan2
- ZZEF1 | c.6254C>T p.S2085F | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101067811; called by muse, mutect2, varscan2
- ABCA12 | c.5098G>A p.V1700M (on ENST00000272895 / NM_173076.3; = p.V1382M on NM_015657.3) | Missense Mutation (SNP) | VAF 39/398 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ABCA5 | c.2327T>C p.V776A | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABI1 | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- ABTB1 | c.753del p.E252Sfs*102 (on ENST00000232744 / NM_172027.3; = p.E110Sfs*102 on NM_032548.3) | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- ABTB2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- AC013477.1 | c.2599A>G p.T867A | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- AC100868.1 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ACSF2 | c.1821G>T p.E607D | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ACSL1 | c.1400G>A p.C467Y | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ADAMTS5 | c.2342dup p.N781Kfs*3 | Frame Shift Ins (INS) | VAF 31/239 reads (13%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.1251del p.R420Gfs*50 | Frame Shift Del (DEL) | VAF 14/111 reads (13%) | called by mutect2, pindel, varscan2
- ADARB2 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- ADAT3 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2
- ADGRA3 | c.3902del p.L1301Cfs*33 | Frame Shift Del (DEL) | VAF 19/170 reads (11%) | called by pindel, varscan2
- ADGRB1 | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALMS1 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- ALPK3 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ALPK3 | c.1760C>A p.P587H | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- AMD1 | c.399A>C p.E133D | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANK2 | c.9058T>C p.S3020P | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 71/459 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ANKRD12 | c.5280del p.D1761Tfs*11 | Frame Shift Del (DEL) | VAF 18/170 reads (11%) | called by mutect2, pindel, varscan2
- ANKRD28 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 43/322 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD31 | c.2456A>G p.Q819R | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ANXA10 | c.924T>A p.H308Q | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- AP3S2 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 17/216 reads (8%) | called by muse, mutect2
- ARF5 | c.409A>C p.S137R | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ARID1A | c.3756del p.N1253Tfs*16 | Frame Shift Del (DEL) | VAF 20/119 reads (17%) | called by mutect2, pindel, varscan2
- ARID1B | c.707G>A p.S236N | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASH1L | c.8816del p.N2939Mfs*5 (on ENST00000368346 / NM_001366177.2; = p.N2934Mfs*5 on NM_018489.3) | Frame Shift Del (DEL) | VAF 25/179 reads (14%) | called by mutect2, pindel, varscan2
- B3GAT1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 25/411 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- BCL11B | c.2402G>A p.C801Y (on ENST00000357195 / NM_001282237.2; = p.C730Y on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/480 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BEST1 | c.1692C>A p.H564Q | Missense Mutation (SNP) | VAF 78/572 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BIRC6 | c.13685A>G p.Q4562R | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- BORA | c.650dup p.L218Afs*6 (on ENST00000613797; = p.L143Afs*6 on NM_024808.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 19/133 reads (14%) | called by mutect2, pindel, varscan2
- BRCA2 | c.9832C>T p.P3278S | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRD8 | c.2250-4_2250-3del | Splice Region (DEL) | VAF 10/68 reads (15%) | called by mutect2, varscan2
- C11orf95 | c.1760del p.G587Afs*4 | Frame Shift Del (DEL) | VAF 22/158 reads (14%) | called by mutect2, pindel
- C17orf80 | c.1117A>T p.S373C | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- C4B | c.3536del p.L1179Wfs*22 | Frame Shift Del (DEL) | VAF 127/990 reads (13%) | called by mutect2, pindel, varscan2
- C4orf54 | c.3209G>T p.R1070M | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- CABIN1 | c.3413C>T p.S1138F | Missense Mutation (SNP) | VAF 80/579 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CADM1 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 19/501 reads (4%) | called by muse, mutect2
- CALCOCO1 | c.1127C>T p.T376I | Missense Mutation (SNP) | VAF 132/727 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN15 | c.826del p.Q276Rfs*11 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- CASQ2 | c.533-2A>G p.X178_splice | Splice Site (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2
- CASR | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 18/337 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.572); called by muse, mutect2
- CASZ1 | c.538T>C p.S180P | Missense Mutation (SNP) | VAF 55/459 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CCDC181 | c.97dup p.S33Kfs*2 | Frame Shift Ins (INS) | VAF 12/109 reads (11%) | called by mutect2, pindel, varscan2
- CCM2 | c.242A>T p.N81I | Missense Mutation (SNP) | VAF 45/345 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CD1E | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDK6 | c.308A>G p.Q103R | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDT1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 73/476 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CENPF | c.1583-1G>A p.X528_splice | Splice Site (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- CFAP65 | c.4153G>A p.D1385N | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CFAP97D1 | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHCHD6 | c.668A>C p.K223T | Missense Mutation (SNP) | VAF 100/654 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CHFR | c.766del p.V256* (on ENST00000432561 / NM_001161345.1; = p.V215* on NM_018223.2) | Frame Shift Del (DEL) | VAF 13/99 reads (13%) | called by mutect2, pindel, varscan2
- CHST3 | c.*5dup | Frame Shift Ins (INS) | VAF 14/87 reads (16%) | called by mutect2, pindel, varscan2
- CIAO2B | c.142+1A>C p.X48_splice | Splice Site (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- CNNM4 | c.937A>G p.T313A | Missense Mutation (SNP) | VAF 73/523 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CNTFR | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CNTN4 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- COQ8A | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CPT1A | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 16/500 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- CPT1C | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 30/216 reads (14%) | called by muse, mutect2, varscan2
- CSAD | c.728C>A p.A243D (on ENST00000444623 / NM_001244705.2; = p.A270D on NM_015989.5) | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CSPG4 | c.4704del p.G1569Dfs*6 | Frame Shift Del (DEL) | VAF 48/373 reads (13%) | called by mutect2, pindel, varscan2
- CSTF2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CTNND1 | c.2764del p.D922Ifs*2 (on ENST00000399050 / NM_001085458.2; = p.D895Ifs*2 on NM_001331.3) | Frame Shift Del (DEL) | VAF 24/187 reads (13%) | called by mutect2, pindel, varscan2
- CTTNBP2 | c.104C>G p.T35S | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CYB5D2 | c.87G>T p.W29C | Missense Mutation (SNP) | VAF 46/414 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- DCAF8L1 | c.1004T>C p.V335A | Missense Mutation (SNP) | VAF 69/357 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- DDN | c.1393C>A p.Q465K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- DDX18 | c.210T>G p.N70K | Missense Mutation (SNP) | VAF 67/394 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DEFB135 | c.152del p.N51Tfs*16 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | called by mutect2, pindel, varscan2
- DHPS | c.491A>T p.N164I | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DLK2 | c.838dup p.H280Pfs*25 | Frame Shift Ins (INS) | VAF 26/204 reads (13%) | called by mutect2, varscan2
- DMD | c.758T>A p.M253K | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DNA2 | c.2027G>A p.S676N | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- DNAJC8 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); called by muse, varscan2
- DRD2 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 30/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DTX4 | c.1080del p.V361Sfs*6 | Frame Shift Del (DEL) | VAF 33/263 reads (13%) | called by mutect2, pindel, varscan2
- DUOX2 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- DUSP21 | c.157A>G p.N53D | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EDC4 | c.3899_3900del p.V1300Gfs*28 | Frame Shift Del (DEL) | VAF 44/376 reads (12%) | called by pindel, varscan2
- EFTUD2 | c.388A>G p.R130G | Missense Mutation (SNP) | VAF 49/347 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELF3 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ELP4 | c.548A>G p.H183R (on ENST00000350638; = p.H182R on NM_019040.5) | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- EPRS1 | c.3025A>G p.K1009E | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2
- ERN2 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ESCO2 | c.1762T>C p.Y588H | Missense Mutation (SNP) | VAF 52/311 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXPH5 | c.2414G>A p.G805D | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.065); called by muse, mutect2
- FAM102B | c.1004dup p.S336Kfs*12 | Frame Shift Ins (INS) | VAF 31/207 reads (15%) | called by mutect2, pindel, varscan2
- FBLN1 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 63/433 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FFAR4 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 69/470 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FLG2 | c.4760G>A p.G1587E | Missense Mutation (SNP) | VAF 40/395 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG2 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 33/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- FOXP4 | c.636del p.L214Sfs*153 (on ENST00000307972 / NM_001012426.1; = p.L214Sfs*152 on NM_138457.3) | Frame Shift Del (DEL) | VAF 23/177 reads (13%) | called by mutect2, pindel, varscan2
- FOXR2 | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- FPGS | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- FTCDNL1 | c.166T>C p.Y56H | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FUT8 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FZR1 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GADL1 | c.707T>A p.V236D | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GALNT11 | c.1233+1G>A p.X411_splice | Splice Site (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- GARS1 | c.1039A>G p.T347A | Missense Mutation (SNP) | VAF 15/241 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2
- GATA6 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 101/862 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- GCC2 | c.2700dup p.C901Mfs*7 | Frame Shift Ins (INS) | VAF 8/66 reads (12%) | called by mutect2, pindel
- GFOD2 | c.695del p.G232Vfs*6 | Frame Shift Del (DEL) | VAF 52/373 reads (14%) | called by mutect2, pindel, varscan2
- GOLGA6B | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 70/469 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, varscan2
- GPR107 | c.1660T>C p.Y554H (on ENST00000372406 / NM_001136557.2; = p.Y506H on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/325 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GRIN3A | c.1674del p.F558Lfs*30 | Frame Shift Del (DEL) | VAF 75/521 reads (14%) | called by mutect2, varscan2
- GRM7 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- GSTT2B | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by mutect2, varscan2
- GTF2B | c.278T>G p.F93C | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HADHB | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 52/425 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- HAUS4 | c.592A>T p.K198* | Nonsense Mutation (SNP) | VAF 32/187 reads (17%) | called by muse, mutect2, varscan2
- HCN2 | c.1864G>A p.V622M | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEATR5B | c.6170C>T p.A2057V | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2
- HELZ2 | c.279-3del | Splice Region (DEL) | VAF 11/78 reads (14%) | called by mutect2, varscan2
- HHIPL1 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 51/386 reads (13%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HMMR | c.379del p.T127Hfs*17 | Frame Shift Del (DEL) | VAF 31/249 reads (12%) | called by mutect2, pindel, varscan2
- HNRNPH1 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 61/447 reads (14%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HPS5 | c.3196G>A p.A1066T (on ENST00000349215 / NM_181507.2; = p.A952T on NM_007216.4) | Missense Mutation (SNP) | VAF 68/487 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- HSPA2 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 63/551 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPB1 | c.180del p.A61Pfs*49 | Frame Shift Del (DEL) | VAF 32/312 reads (10%) | called by mutect2, pindel
- IER2 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- IFNGR1 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 67/402 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- IGLV3-22 | c.100G>T p.G34* | Nonsense Mutation (SNP) | VAF 25/226 reads (11%) | called by muse, mutect2, varscan2
- IGSF9B | c.3351del p.A1118Pfs*13 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- IL23A | c.238del p.Q80Kfs*18 | Frame Shift Del (DEL) | VAF 36/275 reads (13%) | called by mutect2, pindel, varscan2
- INPP4A | c.2870A>G p.Q957R (on ENST00000074304 / NM_001134224.1; = p.Q918R on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- INPP5F | c.3120del p.T1041Pfs*15 | Frame Shift Del (DEL) | VAF 57/467 reads (12%) | called by mutect2, pindel, varscan2
- IRX3 | c.1020del p.A341Pfs*182 | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | called by mutect2, pindel, varscan2
- ITGB8 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITIH5 | c.1801C>A p.L601M | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ITSN1 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 60/474 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- JARID2 | c.181+1G>A p.X61_splice | Splice Site (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- KBTBD11 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.119); called by muse, mutect2
- KCNN3 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 67/531 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- KDM4B | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 13/355 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2
- KHDRBS2 | c.748del p.A250Hfs*60 | Frame Shift Del (DEL) | VAF 35/183 reads (19%) | called by mutect2, pindel, varscan2
- KIAA2026 | c.553_576del p.E186_L193del | In Frame Del (DEL) | VAF 38/202 reads (19%) | called by mutect2, pindel
- KIF2A | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- KPNB1 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KRT2 | c.1111T>C p.Y371H | Missense Mutation (SNP) | VAF 69/498 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA1 | c.3083G>A p.C1028Y | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LHFPL5 | c.109T>A p.S37T | Missense Mutation (SNP) | VAF 88/644 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- LRRC4 | c.649dup p.L217Pfs*16 | Frame Shift Ins (INS) | VAF 40/262 reads (15%) | called by mutect2, pindel, varscan2
- LTBP1 | c.3298T>C p.S1100P (on ENST00000404816 / NM_206943.4; = p.S774P on NM_000627.4) | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LTN1 | c.2581del p.T861Hfs*11 | Frame Shift Del (DEL) | VAF 18/125 reads (14%) | called by mutect2, pindel, varscan2
- LYPD6B | c.116C>T p.A39V (on ENST00000409029 / NM_001317004.1; = p.A63V on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MADCAM1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 53/448 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAF | c.731del p.G244Afs*24 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, varscan2
- MAN2B2 | c.2893C>T p.H965Y | Missense Mutation (SNP) | VAF 31/339 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.329); called by muse, mutect2
- MAP10 | c.1127T>C p.L376P | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MARCHF8 | c.394A>G p.M132V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MARCKSL1 | c.246del p.K83Rfs*18 | Frame Shift Del (DEL) | VAF 11/105 reads (10%) | called by mutect2, pindel
- MGA | c.7712T>C p.L2571S (on ENST00000219905 / NM_001164273.1; = p.L2362S on NM_001080541.2) | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MICA | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2
- MKI67 | c.4369del p.T1457Lfs*8 | Frame Shift Del (DEL) | VAF 62/434 reads (14%) | called by mutect2, pindel, varscan2
- MOGAT2 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MORF4L2 | c.564A>T p.E188D | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- MPHOSPH9 | c.1940G>A p.C647Y | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MPZ | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- MROH2B | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- MRPL28 | c.523del p.Q175Sfs*60 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel, varscan2
- MRPS31 | c.161del p.N54Ifs*12 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | called by mutect2, pindel, varscan2
- MSANTD3 | c.584del p.K195Rfs*18 | Frame Shift Del (DEL) | VAF 38/281 reads (14%) | called by mutect2, pindel, varscan2
- MTARC2 | c.571T>G p.S191A | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- MTF1 | c.513_516del p.C172Ifs*45 | Frame Shift Del (DEL) | VAF 58/455 reads (13%) | called by mutect2, pindel, varscan2
- MUC20 | c.1976del p.N659Mfs*9 | Frame Shift Del (DEL) | VAF 35/329 reads (11%) | called by mutect2, pindel, varscan2
- MUC6 | c.6511C>T p.H2171Y | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MX2 | c.2062A>G p.K688E | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- NAV2 | c.6825G>A p.W2275* (on ENST00000396087 / NM_001244963.2; = p.W2216* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | called by muse, varscan2
- NCF2 | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- NCR2 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NFATC2IP | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- NIPBL | c.6359T>A p.L2120* | Nonsense Mutation (SNP) | VAF 27/187 reads (14%) | called by muse, mutect2, varscan2
- NKAIN4 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NKX2-4 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NKX2-8 | c.106del p.Q36Sfs*104 | Frame Shift Del (DEL) | VAF 16/121 reads (13%) | called by mutect2, pindel, varscan2
- NKX3-2 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- NMBR | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2
- NOSTRIN | c.394C>A p.Q132K (on ENST00000317647 / NM_001039724.4; = p.Q54K on NM_052946.3) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- NOTCH2 | c.3557A>G p.Y1186C | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- NOTCH3 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 87/695 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPLOC4 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NTN5 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 53/277 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- NUS1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NXPE3 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 44/330 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR9K2 | c.136C>A p.P46T (on ENST00000305377; = p.P24T on NM_001005243.1) | Missense Mutation (SNP) | VAF 54/390 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OXER1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 78/448 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PALLD | c.3170A>G p.Q1057R (on ENST00000505667 / NM_001166108.2; = p.Q1040R on NM_016081.4) | Missense Mutation (SNP) | VAF 18/576 reads (3%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.958); called by muse, mutect2
- PARP1 | c.461T>A p.I154N | Missense Mutation (SNP) | VAF 87/820 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- PBRM1 | c.773dup p.N258Kfs*6 | Frame Shift Ins (INS) | VAF 24/214 reads (11%) | called by pindel, varscan2
- PCDHGA11 | c.1487C>A p.T496N | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- PCDHGB5 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 89/530 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PCLO | c.15188dup p.V5064Gfs*12 | Frame Shift Ins (INS) | VAF 23/115 reads (20%) | called by mutect2, varscan2
- PCNX1 | c.1701dup p.R568Tfs*3 | Frame Shift Ins (INS) | VAF 28/242 reads (12%) | called by mutect2, varscan2
- PDGFC | c.832A>G p.K278E | Missense Mutation (SNP) | VAF 70/525 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- PGLYRP3 | c.187del p.C63Afs*16 | Frame Shift Del (DEL) | VAF 66/628 reads (11%) | called by mutect2, pindel, varscan2
- PGM1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 52/385 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PHACTR4 | c.1780A>G p.T594A (on ENST00000373839 / NM_001350159.2; = p.T604A on NM_023923.4) | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- PHF21B | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PIK3R1 | c.244del p.I82Sfs*32 | Frame Shift Del (DEL) | VAF 23/239 reads (10%) | called by mutect2, pindel
- PLCD1 | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 81/442 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCH1 | c.1975G>A p.A659T (on ENST00000340059 / NM_001130960.2; = p.A671T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/254 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PODXL | c.1136T>C p.L379P (on ENST00000378555 / NM_001018111.3; = p.L347P on NM_005397.4) | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- POTEM | c.1092_1093del p.Q364Hfs*7 | Frame Shift Del (DEL) | VAF 3/21 reads (14%) | called by mutect2, varscan2
- PPP1R2C | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 80/527 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP6R2 | c.475A>G p.T159A | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- PRDM10 | c.393G>T p.E131D | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PROM1 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRPF19 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRPF31 | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 89/607 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRRG3 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRSS35 | c.917T>C p.M306T | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PTPRN2 | c.774dup p.G259Rfs*62 | Frame Shift Ins (INS) | VAF 9/77 reads (12%) | called by mutect2, pindel, varscan2
- RAF1 | c.862+8del | Splice Region (DEL) | VAF 69/502 reads (14%) | called by mutect2, pindel, varscan2
- RAPGEF2 | c.1564del p.S522Vfs*12 | Frame Shift Del (DEL) | VAF 52/406 reads (13%) | called by mutect2, pindel, varscan2
- RBM45 | c.732A>C p.E244D (on ENST00000616198 / NM_001365579.1; = p.E242D on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RETREG3 | c.275del p.L92Yfs*6 | Frame Shift Del (DEL) | VAF 16/135 reads (12%) | called by mutect2, varscan2
- RFX7 | c.3355G>A p.A1119T (on ENST00000559447 / NM_001368074.1; = p.A1216T on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- RGS12 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS21 | c.441dup p.W148Mfs*13 | Frame Shift Ins (INS) | VAF 84/273 reads (31%) | called by mutect2, pindel, varscan2
- RICTOR | c.1900C>T p.L634F | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- RINT1 | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RNASE9 | c.272del p.N91Mfs*47 | Frame Shift Del (DEL) | VAF 16/132 reads (12%) | called by mutect2, pindel, varscan2
- RNF144B | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 77/626 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RNF145 | c.1142G>A p.R381H (on ENST00000424310 / NM_001199383.2; = p.R409H on NM_144726.2) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF208 | c.679T>G p.W227G | Missense Mutation (SNP) | VAF 53/373 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RNF225 | c.46del p.Q16Rfs*? | Frame Shift Del (DEL) | VAF 24/154 reads (16%) | called by mutect2, pindel, varscan2
- RNF24 | c.119T>A p.L40* | Nonsense Mutation (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- RNPS1 | c.426A>T p.K142N | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ROBO1 | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- RPUSD2 | c.1345T>A p.L449M | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- SBF2 | c.5200A>G p.S1734G | Missense Mutation (SNP) | VAF 64/418 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SCARF2 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SCART1 | c.683-3del | Splice Region (DEL) | VAF 82/542 reads (15%) | called by mutect2, pindel, varscan2
- SCFD2 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SELENBP1 | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 33/344 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SEMA4C | c.2271del p.P759Lfs*36 | Frame Shift Del (DEL) | VAF 44/274 reads (16%) | called by mutect2, pindel, varscan2
- SERPINB10 | c.732A>T p.K244N | Missense Mutation (SNP) | VAF 60/421 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHISAL1 | c.239T>C p.M80T | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SIAH1 | c.776T>A p.F259Y | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLC17A3 | c.668T>C p.L223S | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); called by muse, varscan2
- SLC18A3 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- SLC22A10 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SLC24A3 | c.1020del p.K341Rfs*11 | Frame Shift Del (DEL) | VAF 44/313 reads (14%) | called by pindel, varscan2
- SLC30A4 | c.1002T>C p.G334= | Splice Region (SNP) | VAF 15/74 reads (20%) | called by muse, varscan2
- SLC35A2 | c.92-1G>A p.X31_splice | Splice Site (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2
- SLC4A4 | c.831A>T p.K277N (on ENST00000264485 / NM_001098484.3; = p.K233N on NM_003759.4) | Missense Mutation (SNP) | VAF 75/449 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SLMAP | c.2022+4A>C | Splice Region (SNP) | VAF 35/312 reads (11%) | called by muse, mutect2, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by mutect2, varscan2
- SMYD4 | c.2011G>T p.G671C | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SOGA1 | c.1421T>G p.L474R | Missense Mutation (SNP) | VAF 51/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPACA1 | c.707T>C p.L236S | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SPATA22 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SPEG | c.5742del p.S1915Vfs*324 | Frame Shift Del (DEL) | VAF 25/136 reads (18%) | called by mutect2, pindel, varscan2
- SPTBN2 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SRCIN1 | c.113del p.G38Afs*22 | Frame Shift Del (DEL) | VAF 40/276 reads (14%) | called by mutect2, pindel, varscan2
- STYXL2 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SV2A | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TAAR5 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TACC2 | c.8230C>T p.Q2744* (on ENST00000334433; = p.Q822* on NM_006997.4) | Nonsense Mutation (SNP) | VAF 28/155 reads (18%) | called by muse, mutect2, varscan2
- TAF6 | c.676_678del p.E226del | In Frame Del (DEL) | VAF 37/263 reads (14%) | called by mutect2, pindel, varscan2
- TDRKH | c.610A>T p.I204F | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2
- TENM4 | c.4530del p.S1511Vfs*26 | Frame Shift Del (DEL) | VAF 34/279 reads (12%) | called by mutect2, pindel, varscan2
- TET1 | c.774del p.V260Lfs*11 | Frame Shift Del (DEL) | VAF 40/267 reads (15%) | called by mutect2, pindel, varscan2
- TEX35 | c.71T>C p.L24S | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- THBD | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TIMELESS | c.1522C>A p.L508I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- TJP1 | c.2265C>A p.Y755* | Nonsense Mutation (SNP) | VAF 27/191 reads (14%) | called by muse, mutect2, varscan2
- TLR5 | c.800C>A p.A267D | Missense Mutation (SNP) | VAF 57/546 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- TLR7 | c.2335C>A p.L779I | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TMEM106B | c.749A>C p.Y250S | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM121 | c.17del p.P6Rfs*8 | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | called by mutect2, pindel, varscan2
- TMEM156 | c.56del p.L19* | Frame Shift Del (DEL) | VAF 32/205 reads (16%) | called by mutect2, pindel, varscan2
- TNMD | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 42/512 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- TOMM40L | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- TPST2 | c.989del p.N330Tfs*20 | Frame Shift Del (DEL) | VAF 25/167 reads (15%) | called by mutect2, pindel, varscan2
- TRIM62 | c.1117A>G p.S373G | Missense Mutation (SNP) | VAF 61/302 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- TRIM71 | c.131del p.G44Afs*55 | Frame Shift Del (DEL) | VAF 18/120 reads (15%) | called by mutect2, pindel
- TRMT13 | c.627del p.V210Ffs*5 | Frame Shift Del (DEL) | VAF 25/150 reads (17%) | called by mutect2, pindel, varscan2
- TSBP1 | c.644A>G p.Y215C (on ENST00000617061; = p.Y218C on NM_006781.5) | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TSHZ3 | c.3038A>G p.Q1013R | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- TSPAN31 | c.113_118del p.G38_L39del | In Frame Del (DEL) | VAF 30/173 reads (17%) | called by mutect2, pindel, varscan2
- TTC25 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, varscan2
- TTC36 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 51/357 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBR5 | c.2774C>T p.A925V | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- ULK1 | c.2854G>A p.G952S | Missense Mutation (SNP) | VAF 36/383 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- UPF1 | c.3194T>C p.L1065P (on ENST00000599848 / NM_001297549.2; = p.L1054P on NM_002911.4) | Missense Mutation (SNP) | VAF 78/618 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USO1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- USP13 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP20 | c.1229del p.P410Lfs*6 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- VPS13A | c.7588G>A p.D2530N | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- WDFY3 | c.483dup p.D162* | Frame Shift Ins (INS) | VAF 23/171 reads (13%) | called by mutect2, pindel, varscan2
- WDR6 | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- XAB2 | c.1983C>A p.D661E | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- XIAP | c.231C>G p.D77E | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBED6 | c.886A>G p.R296G | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZBTB40 | c.1220T>C p.L407S | Missense Mutation (SNP) | VAF 58/392 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ZCCHC9 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- ZFP69 | c.*3del | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- ZFYVE9 | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMPSTE24 | c.471A>T p.Q157H | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZMYM4 | c.3119C>T p.T1040I | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF182 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF236 | c.3553C>T p.H1185Y | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF326 | c.833del p.N278Mfs*63 | Frame Shift Del (DEL) | VAF 19/145 reads (13%) | called by mutect2, pindel, varscan2
- ZNF570 | c.839G>T p.R280M | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF576 | c.335T>C p.F112S | Missense Mutation (SNP) | VAF 75/530 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZSCAN5B | c.1462del p.T488Hfs*24 | Frame Shift Del (DEL) | VAF 15/101 reads (15%) | called by mutect2, pindel, varscan2
- ZSWIM6 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- ZXDB | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 23/255 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ABCA7 | c.2613C>T p.D871= | Silent (SNP) | VAF 33/235 reads (14%) | called by muse, mutect2, varscan2
- ABCC1 | c.1290C>T p.D430= | Silent (SNP) | VAF 48/329 reads (15%) | catalogued as rs371886235, COSV60683300; called by muse, mutect2, varscan2
- ACRBP | c.273C>T p.C91= | Silent (SNP) | VAF 36/228 reads (16%) | catalogued as rs930440159; called by muse, mutect2, varscan2
- ACSM2A | c.273G>A p.Q91= (on ENST00000219054; = p.Q12= on NM_001308169.2) | Silent (SNP) | VAF 31/621 reads (5%) | catalogued as rs769037621; called by muse, mutect2
- ACSM2B | c.273G>A p.Q91= | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as rs1348263922, COSV61660316; called by muse, mutect2, varscan2
- ADAMTS1 | c.2823G>A p.G941= | Silent (SNP) | VAF 36/316 reads (11%) | catalogued as COSV53170238; called by muse, mutect2, varscan2
- ADGRG4 | c.438G>T p.T146= | Silent (SNP) | VAF 51/318 reads (16%) | catalogued as COSV99796135; called by muse, mutect2, varscan2
- AFF2 | c.738G>A p.V246= | Silent (SNP) | VAF 10/287 reads (3%) | catalogued as rs1557257933; called by muse, mutect2
- AFF3 | c.3318G>A p.P1106= | Silent (SNP) | VAF 37/304 reads (12%) | catalogued as rs147667483; called by muse, mutect2, varscan2
- AGPAT1 | c.597G>A p.V199= | Silent (SNP) | VAF 70/381 reads (18%) | called by muse, mutect2, varscan2
- AKAP13 | c.7770G>A p.Q2590= (on ENST00000394518 / NM_007200.5; = p.Q2594= on NM_006738.6) | Silent (SNP) | VAF 89/537 reads (17%) | catalogued as rs1052730605; called by muse, mutect2, varscan2
- ANXA6 | c.1311C>A p.A437= | Silent (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- AP3B2 | c.801A>G p.K267= | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- APOB | c.5430C>T p.N1810= | Silent (SNP) | VAF 38/267 reads (14%) | catalogued as rs1352777306; called by muse, mutect2, varscan2
- ARMH1 | c.1044G>A p.T348= | Silent (SNP) | VAF 36/199 reads (18%) | catalogued as rs961848655; called by muse, mutect2, varscan2
- ASB11 | c.459C>T p.F153= | Silent (SNP) | VAF 30/250 reads (12%) | catalogued as rs1442430312, COSV60356062; called by muse, mutect2, varscan2
- ASCC2 | c.48G>A p.P16= | Silent (SNP) | VAF 47/333 reads (14%) | catalogued as rs770347429, COSV100316101; called by muse, mutect2, varscan2
- ASPM | c.3420C>T p.D1140= | Silent (SNP) | VAF 62/546 reads (11%) | catalogued as rs186076559; called by muse, mutect2, varscan2
- ATG4C | c.174G>A p.T58= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs756364947; called by muse, mutect2, varscan2
- BAHCC1 | c.3735G>A p.E1245= | Silent (SNP) | VAF 62/372 reads (17%) | called by muse, mutect2, varscan2
- BMPR2 | c.297T>C p.C99= | Silent (SNP) | VAF 71/438 reads (16%) | called by muse, mutect2, varscan2
- BRPF1 | c.3432C>T p.L1144= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs762856879; called by muse, mutect2, varscan2
- BSND | c.771G>A p.Q257= | Silent (SNP) | VAF 100/615 reads (16%) | called by muse, mutect2, varscan2
- C1QTNF4 | c.507G>A p.P169= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- CAPN9 | c.492C>T p.D164= | Silent (SNP) | VAF 32/272 reads (12%) | called by muse, mutect2, varscan2
- CATSPERZ | c.165G>A p.E55= | Silent (SNP) | VAF 36/265 reads (14%) | catalogued as rs1452160501; called by muse, mutect2, varscan2
- CCDC168 | c.2457A>G p.E819= | Silent (SNP) | VAF 33/246 reads (13%) | catalogued as rs1461677758; called by muse, mutect2, varscan2
- CDC42BPA | c.4893C>T p.S1631= (on ENST00000334218 / NM_001366019.2; = p.S1618= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/579 reads (10%) | called by muse, mutect2, varscan2
- CETN3 | c.438T>C p.F146= | Silent (SNP) | VAF 22/302 reads (7%) | called by muse, mutect2
- CFL1 | c.192C>T p.V64= | Silent (SNP) | VAF 58/448 reads (13%) | catalogued as rs11550148; called by muse, mutect2, varscan2
- CGAS | c.408C>A p.P136= | Silent (SNP) | VAF 76/456 reads (17%) | called by muse, mutect2, varscan2
- CGB2 | c.303C>T p.A101= | Silent (SNP) | VAF 50/842 reads (6%) | catalogued as rs772638632; called by muse, mutect2
- CILP | c.3279C>T p.G1093= | Silent (SNP) | VAF 24/238 reads (10%) | catalogued as COSV56024432; called by muse, mutect2, varscan2
- CLK1 | c.468A>T p.V156= | Silent (SNP) | VAF 39/219 reads (18%) | called by muse, mutect2, varscan2
- CNTN1 | c.396T>C p.F132= | Silent (SNP) | VAF 66/394 reads (17%) | called by muse, mutect2, varscan2
- COG2 | c.690C>T p.C230= | Silent (SNP) | VAF 30/352 reads (9%) | called by muse, mutect2
- COL21A1 | c.1869G>A p.G623= | Silent (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- COL4A6 | c.2565A>G p.G855= | Silent (SNP) | VAF 36/247 reads (15%) | catalogued as COSV57865898; called by muse, mutect2, varscan2
- COL5A3 | c.186C>T p.D62= | Silent (SNP) | VAF 32/306 reads (10%) | catalogued as COSV53416460; called by muse, mutect2, varscan2
- CPNE6 | c.228C>A p.A76= | Silent (SNP) | VAF 43/239 reads (18%) | called by muse, mutect2, varscan2
- CRAT | c.78C>T p.S26= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- CRB2 | c.471C>T p.H157= | Silent (SNP) | VAF 49/291 reads (17%) | catalogued as rs113157023, COSV63504000; called by muse, mutect2, varscan2
- CROCC | c.1350G>A p.Q450= | Silent (SNP) | VAF 27/199 reads (14%) | catalogued as rs1293068557; called by muse, mutect2, varscan2
- CROCC2 | c.2616C>T p.A872= | Silent (SNP) | VAF 40/254 reads (16%) | catalogued as rs1418844542; called by muse, mutect2, varscan2
- CSRNP1 | c.120C>A p.S40= | Silent (SNP) | VAF 33/198 reads (17%) | called by muse, mutect2, varscan2
- CUX2 | c.2547G>A p.T849= | Silent (SNP) | VAF 23/157 reads (15%) | catalogued as rs1186742017; called by muse, mutect2, varscan2
- CYLC2 | c.909T>C p.V303= | Silent (SNP) | VAF 26/256 reads (10%) | called by muse, mutect2, varscan2
- DAPK1 | c.2097G>A p.G699= | Silent (SNP) | VAF 47/354 reads (13%) | catalogued as rs1019151279; called by muse, mutect2, varscan2
- DCAF12L2 | c.567C>T p.D189= | Silent (SNP) | VAF 67/447 reads (15%) | called by muse, mutect2, varscan2
- DCST1 | c.654A>C p.T218= | Silent (SNP) | VAF 95/743 reads (13%) | called by muse, mutect2, varscan2
- DDX58 | c.1647T>C p.N549= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1193496361; called by muse, mutect2, varscan2
- DEPDC1B | c.222G>A p.Q74= | Silent (SNP) | VAF 27/506 reads (5%) | called by muse, mutect2
- DNAJA1 | c.1119G>T p.R373= | Silent (SNP) | VAF 59/447 reads (13%) | called by muse, mutect2, varscan2
- ENTPD6 | c.1158C>T p.Y386= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as rs769540342, COSV100737079, COSV61750820; called by muse, mutect2, varscan2
- EXOC7 | c.501C>T p.P167= | Silent (SNP) | VAF 59/413 reads (14%) | catalogued as rs749143994, COSV58739299; called by muse, mutect2, varscan2
- FAT1 | c.8145C>T p.D2715= | Silent (SNP) | VAF 27/216 reads (13%) | catalogued as rs369653159; called by muse, mutect2, varscan2
- FBLN1 | c.1833C>T p.R611= | Silent (SNP) | VAF 43/308 reads (14%) | catalogued as rs142001473; called by muse, mutect2, varscan2
- FGD5 | c.3732C>T p.H1244= | Silent (SNP) | VAF 65/449 reads (14%) | catalogued as rs763455633; called by muse, mutect2, varscan2
- FNIP2 | c.2553G>A p.E851= | Silent (SNP) | VAF 10/264 reads (4%) | catalogued as rs1438941955; called by muse, mutect2
- FOXE3 | c.834C>T p.P278= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as rs886042525; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FOXI3 | c.624C>T p.R208= | Silent (SNP) | VAF 70/467 reads (15%) | catalogued as COSV101230936; called by muse, mutect2, varscan2
- FRMPD1 | c.567T>C p.N189= | Silent (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- FUT5 | c.636C>T p.N212= | Silent (SNP) | VAF 20/684 reads (3%) | catalogued as rs980401148; called by muse, mutect2
- GALNT14 | c.1569C>T p.F523= | Silent (SNP) | VAF 29/290 reads (10%) | catalogued as rs770358878, COSV100204248; called by muse, mutect2, varscan2
- GCNT1 | c.810G>T p.G270= | Silent (SNP) | VAF 38/248 reads (15%) | called by muse, mutect2, varscan2
- GFRA3 | c.636G>A p.A212= | Silent (SNP) | VAF 36/228 reads (16%) | catalogued as COSV99218418; called by muse, mutect2, varscan2
- GLG1 | c.2523C>T p.N841= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as rs373580952; called by muse, mutect2, varscan2
- GLI1 | c.1872C>T p.A624= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as rs758285802; called by muse, mutect2, varscan2
- GLUL | c.1092C>T p.T364= | Silent (SNP) | VAF 50/450 reads (11%) | catalogued as rs778907542; called by mutect2, varscan2
- GRIK5 | c.2553C>T p.H851= | Silent (SNP) | VAF 78/478 reads (16%) | called by muse, mutect2, varscan2
- GRIK5 | c.426C>T p.N142= | Silent (SNP) | VAF 61/408 reads (15%) | catalogued as rs745782468, COSV53479366; called by muse, mutect2, varscan2
- GRM2 | c.2583C>T p.G861= | Silent (SNP) | VAF 57/423 reads (13%) | called by muse, mutect2, varscan2
- GRM8 | c.1392C>T p.N464= | Silent (SNP) | VAF 29/217 reads (13%) | catalogued as rs766249414, COSV58849459; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2565C>T p.Y855= (on ENST00000265755 / NM_016328.3; = p.Y840= on NM_005685.4) | Silent (SNP) | VAF 52/255 reads (20%) | catalogued as rs782523451, COSV56091281; called by muse, mutect2, varscan2
- HECTD4 | c.633A>G p.R211= | Silent (SNP) | VAF 77/387 reads (20%) | called by muse, mutect2, varscan2
- HEMGN | c.384G>A p.V128= | Silent (SNP) | VAF 40/228 reads (18%) | called by muse, mutect2, varscan2
- HIPK4 | c.1320G>A p.G440= | Silent (SNP) | VAF 83/536 reads (15%) | called by muse, mutect2, varscan2
- HSD17B2 | c.420G>A p.T140= | Silent (SNP) | VAF 38/285 reads (13%) | catalogued as rs768455795, COSV52276922; called by muse, mutect2, varscan2
- HSF2 | c.1425C>T p.S475= | Silent (SNP) | VAF 35/253 reads (14%) | called by muse, mutect2, varscan2
- HSPB9 | c.159T>C p.G53= | Silent (SNP) | VAF 16/436 reads (4%) | called by muse, mutect2
- IFIT3 | c.870A>G p.R290= | Silent (SNP) | VAF 28/142 reads (20%) | called by muse, mutect2, varscan2
- IGHE | c.837C>T p.T279= | Silent (SNP) | VAF 67/532 reads (13%) | catalogued as rs782328064; called by muse, mutect2, varscan2
- IL1RL1 | c.1590C>T p.H530= | Silent (SNP) | VAF 31/189 reads (16%) | catalogued as rs757400158; called by muse, mutect2, varscan2
- KALRN | c.7566G>A p.T2522= (on ENST00000360013 / NM_001024660.4; = p.T825= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as rs528883360; called by muse, mutect2
- KANK3 | c.1689G>T p.L563= | Silent (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- KCNH4 | c.1284G>A p.A428= | Silent (SNP) | VAF 42/290 reads (14%) | catalogued as rs550145042, COSV99236701; called by muse, mutect2, varscan2
- KCNK12 | c.231C>A p.R77= | Silent (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- KDM5C | c.471C>T p.Y157= | Silent (SNP) | VAF 63/450 reads (14%) | catalogued as rs782147874, COSV62890780; called by muse, mutect2, varscan2
- KIF1C | c.36T>A p.V12= | Silent (SNP) | VAF 17/354 reads (5%) | called by muse, mutect2
- KLHL20 | c.282A>G p.R94= | Silent (SNP) | VAF 36/410 reads (9%) | called by muse, mutect2
- KRT20 | c.1059C>T p.Y353= | Silent (SNP) | VAF 56/367 reads (15%) | called by muse, mutect2, varscan2
- KRTAP29-1 | c.90T>C p.H30= | Silent (SNP) | VAF 54/281 reads (19%) | called by muse, mutect2, varscan2
- KRTAP4-4 | c.474C>A p.P158= | Silent (SNP) | VAF 34/265 reads (13%) | called by muse, mutect2, varscan2
- LAMA3 | c.6258T>G p.T2086= (on ENST00000313654 / NM_198129.4; = p.T477= on NM_000227.6) | Silent (SNP) | VAF 54/347 reads (16%) | called by muse, mutect2, varscan2
- LARP4 | c.1644T>C p.C548= | Silent (SNP) | VAF 25/183 reads (14%) | called by muse, mutect2, varscan2
- LATS2 | c.1179C>T p.H393= | Silent (SNP) | VAF 59/364 reads (16%) | catalogued as rs1027131519, COSV66874363; called by muse, mutect2, varscan2
- LEFTY1 | c.840C>T p.N280= | Silent (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- LZTS1 | c.261C>T p.S87= | Silent (SNP) | VAF 10/264 reads (4%) | catalogued as rs1431971510, COSV56116423; called by muse, mutect2
- MAP3K2 | c.1638T>C p.S546= | Silent (SNP) | VAF 22/212 reads (10%) | called by muse, varscan2
- MATN2 | c.2787C>T p.N929= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs1445180478; called by muse, mutect2, varscan2
- MDGA1 | c.1389C>T p.C463= | Silent (SNP) | VAF 15/290 reads (5%) | catalogued as rs1453955669; called by muse, mutect2
- MED12 | c.3333C>T p.N1111= | Silent (SNP) | VAF 28/228 reads (12%) | catalogued as rs781289776; called by muse, mutect2, varscan2
- MPZ | c.486C>T p.I162= | Silent (SNP) | VAF 39/364 reads (11%) | catalogued as CD1411857, CM023102; called by muse, mutect2, varscan2
212 further variants in this file (0 protein-altering or splice-affecting, 105 silent, 107 other) are not listed here.
